Somatic mutation profile of tumor specimen TCGA-VQ-A8PD-01A (aliquot TCGA-VQ-A8PD-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 69.1 years (25,244 days).
Specimen TCGA-VQ-A8PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b53e61e-60ee-404b-8922-1afbd528ec83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PD-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PD-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8ef7f57-829e-4234-875e-c92b395e6e85

The open-access MAF lists 62 somatic variants for this specimen: 52 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 9, Nonsense Mutation 3, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ERBB3 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1057519803, COSV57246350, COSV57249681; ClinVar: likely pathogenic; called by muse, mutect2
- ZHX3 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201454849, CM121425, COSV58380689; called by muse, mutect2, varscan2
- ACTR8 | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV99213689; called by muse, mutect2
- ACTRT1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64418999, COSV64419064; called by muse, mutect2, varscan2
- AHCTF1 | c.3247G>T p.V1083L (on ENST00000366508; = p.V1057L on NM_015446.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV100403589; called by muse, mutect2, varscan2
- ANKRD30A | c.1572+2T>A p.X524_splice (on ENST00000611781; = p.X468_splice on NM_052997.2) | Splice Site (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100653441; called by muse, mutect2
- ARHGAP1 | c.461A>T p.N154I | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100357905; called by muse, mutect2
- ARID2 | c.2449C>T p.Q817* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100536070; called by muse, mutect2, varscan2
- ARPP21 | c.1957C>A p.Q653K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99491873; called by muse, mutect2
- BUD23 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs561141408, COSV99736553; called by muse, mutect2, varscan2
- C16orf46 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200805640, COSV55151467; called by muse, mutect2, varscan2
- CACNA1H | c.4436G>A p.R1479H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs776023990, COSV62000838; called by muse, mutect2, varscan2
- CTNNA3 | c.1548A>T p.E516D | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV65599554; called by muse, mutect2
- DKK1 | c.246G>A p.P82= | Splice Region (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100906531; called by muse, mutect2
- FLG | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs768202093, COSV100911523; called by muse, mutect2
- GNAO1 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99341122; called by muse, mutect2
- HDAC9 | c.2525T>G p.L842R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV101286734; called by muse, mutect2, varscan2
- HOXA10 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385441; called by muse, mutect2, varscan2
- HOXD3 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV50880048; called by muse, mutect2, varscan2
- HTR2A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as rs1428173433, COSV66326797; called by muse, mutect2, varscan2
- IGF1R | c.3007C>T p.R1003W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51291626; called by muse, mutect2, varscan2
- IQSEC3 | c.1045C>T p.R349W (on ENST00000538872 / NM_001170738.2; = p.R46W on NM_015232.1) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58286189; called by muse, mutect2, varscan2
- KIAA1328 | c.1006A>C p.S336R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99694211; called by muse, mutect2, varscan2
- KLC2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100385073; called by muse, mutect2
- KRT4 | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.429); catalogued as COSV99542893; called by muse, mutect2
- KRT79 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as rs775020026, COSV57942478; called by muse, mutect2, varscan2
- MROH9 | c.1519A>G p.S507G | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63010291, COSV63010569; called by muse, mutect2, varscan2
- NLGN4Y | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52971833; called by muse, mutect2, varscan2
- OR13G1 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100687637, COSV62944217; called by muse, mutect2, varscan2
- OR4C6 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100051612; called by muse, mutect2
- PLXNA4 | c.4675A>T p.S1559C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100324035; called by muse, mutect2
- PRKDC | c.12100G>A p.A4034T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100040367; called by muse, mutect2
- PXDNL | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs558871034, COSV62496125; called by mutect2, varscan2
- RBBP6 | c.2741C>G p.T914R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100154553; called by muse, mutect2, varscan2
- RNF151 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1397082944, COSV100364411; called by muse, mutect2
- SETD2 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs375514539; called by muse, mutect2
- SHISAL1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | catalogued as COSV66987723; called by muse, mutect2, varscan2
- SLC7A4 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs755774555, COSV100298689; called by muse, mutect2
- SLCO5A1 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV99479925; called by muse, mutect2
- SNRPA1 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574552; called by muse, mutect2, varscan2
- SPDYE1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs560250427, COSV51669655, COSV99323960; called by muse, mutect2
- SVIL | c.6433G>A p.V2145M (on ENST00000355867 / NM_021738.3; = p.V1719M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759776112, COSV100881234; called by muse, mutect2, varscan2
- TRMT61B | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs572821530, COSV100066562; called by muse, mutect2, varscan2
- TTN | c.81150A>T p.K27050N (on ENST00000591111; = p.K19626N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | PolyPhen possibly damaging (0.784); catalogued as COSV100610662; called by muse, mutect2
- TTN | c.17828A>G p.K5943R (on ENST00000591111; = p.K5016R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/121 reads (9%) | PolyPhen benign (0.01); catalogued as COSV100610663, COSV100626432; called by muse, mutect2
- VWA8 | c.4896G>A p.M1632I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV101022580; called by muse, mutect2
- ZAN | c.3211C>T p.R1071W | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs773386504, COSV100769663; called by muse, mutect2
- ZBED9 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV101509222; called by muse, mutect2
- ZBTB20 | c.1411C>A p.P471T (on ENST00000474710 / NM_001164342.2; = p.P398T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV100613745; called by muse, mutect2, varscan2
- ZFAT | c.2425A>C p.T809P | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100914546; called by muse, mutect2
- ZFP82 | c.1442A>C p.K481T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101089052; called by muse, mutect2, varscan2
- CNTNAP5 | c.1251G>A p.L417= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV101443484, COSV101443881; called by muse, mutect2
- DPP4 | c.441G>A p.R147= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV100858850; called by muse, mutect2
- ENO2 | c.123G>A p.T41= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs370454404, COSV50397290; called by muse, mutect2, varscan2
- IFT140 | c.2034C>T p.N678= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs1248177030, COSV68491686; called by muse, mutect2, varscan2
- MIGA1 | c.1428C>T p.S476= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100889771; called by muse, mutect2
- PHF3 | c.4503G>A p.E1501= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100013273; called by muse, mutect2
- SERPINB3 | c.963C>T p.R321= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs763567283, COSV52190500; called by muse, mutect2, varscan2
- TCF15 | c.405C>T p.D135= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1304263089, COSV55720436, COSV55721231; called by muse, mutect2
- TMEM119 | c.141G>A p.S47= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs528443188, COSV67188919; called by muse, mutect2, varscan2
- MIR320D2 | n.5C>A | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
